TCGA case TCGA-52-7810 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: University of Miami. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98b86f94-9ede-45ab-ba09-19a6ec6d9494

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.8; Tissue or organ of origin: Overlapping lesion of lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.9 years (22,241 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 923 days (2.5 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 923 days (2.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0.
- Karnofsky performance status: 90; Timepoint: Prior to Adjuvant Therapy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1970; Tobacco smoking quit year: 1990.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-52-7810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-52-7810-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-52-7810-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 61; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
- Sample TCGA-52-7810-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-52-7810-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 923 days; disease-specific survival: no event (censored), 923 days; disease-free interval: no event (censored), 923 days; progression-free interval: no event (censored), 923 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-52-7810-01A-11D-2121-01): tumor purity 0.51, ploidy 3.61, whole-genome doublings 1.
